TCGA case TCGA-DX-A7EL — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef273fe6-aab0-41eb-94f7-cca980bf789e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 56.9 years (20,767 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Inferior Vena Cava / Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5; Tumor length measurement: 7; Tumor width measurement: 5.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Breast, NOS; Classification of tumor: Prior primary; Age at diagnosis: 49.6 years (18,133 days); Days to diagnosis: -2,634 days (-7.2 years).
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 63.0 years (23,016 days); Days to diagnosis: 2,249 days (6.2 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 1.9.

Follow-up (3 entries)
- Day 2,249 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 2,249 days (6.2 years); Discontiguous lesion count: 2.
- Days to follow up: 2,263 days (6.2 years); Disease response: Tumor Free.
- Days to follow up: 2,291 days (6.3 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A7EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 390 mg.
  Slide TCGA-DX-A7EL-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A7EL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A7EL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: Inferior vena cava; Site of primary tumor other: IVC; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 7; Lesion pathologic depth: 5.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Breast excision, lymph node dissection; Days from index date to other malignancy surgery: -2604.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No; Days from index date to radiation therapy started: -2559.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,291 days; disease-specific survival: no event (censored), 2,291 days; disease-free interval: event (new tumor event after initially disease-free), 2,249 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,249 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A7EL-01A-12D-A40C-01): tumor purity 0.72, ploidy 2.06, whole-genome doublings 0.
